Surgical pathology report (de-identified scan), TCGA case TCGA-19-5952, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-5952-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

TCGA - 19 - 5952

FINAL DIAGNOSIS

A. LEFT POSTERIOR TEMPORAL BRAIN LESION AND B. CUSA ASPIRANT, REMOVAL:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Electronically Signed Out By [REDACTED]

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Clinical History:

left temporal lesion

Specimens Submitted As:

A: LEFT POSTERIOR TEMPORAL BRAIN LESION
B: CUSA ASPIRANT

Gross Description:

A: Received in formalin, labeled with the patient's name, number, and "A: Left posterior temporal brain lesion", are multiple light tan to red-brown irregular soft cerebriform tissue fragments measuring 3.5 x 2.6 x 1.3 cm in aggregate. On section, the fragments are light tan. Submitted entirely in three cassettes.

B: Received in formalin, in a collection device, labeled with the patient's name, number, and "B", are multiple light tan irregular soft tissue fragments measuring 1.5 x 0.8 x 0.3 cm in aggregate. Submitted in toto in one cassette.

Source: NCI Genomic Data Commons file 42998e10-df5a-4778-b72e-3ed9fab0e1d2 (TCGA-19-5952.6CE18D81-108B-455B-B6D2-3717AC9866C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).